Surgical pathology report (de-identified scan), TCGA case TCGA-56-A4ZJ, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-A4ZJ-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

1CD-0-3

Carcinoma, squamous cell, non-keratinizing
8072/3

Site: lung, lower lobe 634.3

hw
11/4/12

Pre-Op Diagnosis
Right lower lobe squamous cell cancer
Post-Op Diagnosis
Same as above
Clinical History
Nothing indicated
Gross Description:
Four parts

Received in formalin labeled "[REDACTED] 1 - level 9 lymph node right lung" is a 1.1 x 0.8 x 0.3 cm irregular black soft tissue consistent with probable lymph node, which is bisected and submitted in its entirety in one cassette.

Received in formalin labeled "[REDACTED] 2 - level 10 lymph node right lung" are three irregular granular black soft tissues consistent with probable lymph node ranging from 0.5 x 0.4 x 0.2 cm to 1.1 x 0.7 x 0.3 cm, which are submitted in toto in one cassette.

Received labeled "[REDACTED] 3 - right lower lung lobe" is a 185 gram, 19.4 x 10.5 x 3.2 cm lower lung lobe with an attached 0.8 cm segment of bronchus. The pleura is smooth to wrinkled and tan-pink to gray-purple with black anthracotic areas. There is a 3.1 cm linear staple line adjacent to the hilum. No additional parenchymal staple lines are identified. There is a 1.4 x 1.1 cm slightly ill-defined umbilicated area of pleura 2.2 cm from the hilum. The cut surface of this area consists of a 1.8 x 1.5 x 1.2 cm well circumscribed tan nodule, 3.4 cm from the bronchial margin and 3.8 cm from the staple line. The remainder of the cut surface consists of spongy tan-red parenchyma. There are two tan-white nodules measuring 0.1 cm and 0.2 cm in greatest dimension which abut the pleura near the periphery of the specimen. The nodules are 3.6

[page 2 of 3]
cm from each other. No additional parenchymal lesions are identified. No obvious intraparenchymal or hilar lymph nodes are identified. The specimen is inked, serially sectioned and representative sections are submitted as labeled: A - bronchial and vascular margins (en face); B - pleural margin (perpendicular); C-F - lesion, entirely submitted; G - larger nodule, entirely submitted; H - smaller nodule, in toto. Also received in the same container is a blue, yellow and green cassette labeled ' genomic research study.

Received in formalin labeled "[REDACTED] 4 - level 4 lymph node right lung" is a 2.8 x 1.7 x 0.5 cm irregular fibroadipose tissue bearing three irregular black firm tissues consistent with probable lymph node ranging from 1.1 x 0.5 x 0.3 cm to 1.2 x 0.8 x 0.5 cm. The specimen is sectioned and representative sections are submitted, to include the lymph nodes in their entirety, as labeled: A-C - one lymph node, bisected in each.

[REDACTED]
Microscopic Description:
See diagnosis.

Final Diagnosis

Lymph node, right lung, level 9, excision:
Reactive hyperplasia, negative for malignancy, one node.
Lymph node, right lung, level 10, excision:
Reactive hyperplasia, negative for malignancy, three nodes.
Lung, right lower lobe, lobectomy:

Tumor characteristics:

Specimen integrity: Intact, margins can be evaluated.
Specimen laterality: Right side.
Histologic type: Squamous cell carcinoma, non-keratinizing.
Histologic grade: 2 (moderately differentiated).
Tumor site: Right lower lobe.
Tumor focality: Unifocal.
Tumor size: 1.8 x 1.5 x 1.2 cm.
Visceral pleural invasion: Not identified.
Lymphovascular space invasion: Not identified.
Tumor extension: Not identified.
Treatment effect: Not identified (no specific history provided).
Surgical margin status:
Tumor distance from bronchial margin: 3.4 cm
Tumor distance from stapled margin: 3.8 cm
Tumor distance from pleural surface: 0.1 cm

Lymph node status:

Total number of lymph nodes received (includes all four parts of this case): 10

Total number of lymph nodes containing metastatic carcinoma: 0
Other significant findings:

Two small subpleural fibrous nodules are present consistent with areas of scarring.

pTN stage: pT1a, N0 PAS 9 SPC-NP

Comments

The history of "back lower lobe squamous cell carcinoma" is noted. There is however no prior material identified in our files for review and comparison.

[page 3 of 3]
The two small subpleural nodules identified grossly, separate from the malignancy, are both areas of fibrosis containing some histiocytes and reactive alveolar lining cells, possibly representing areas of resold pneumonia.

At the request of the undersigned pathologist, these slides have been additionally reviewed by Dr. [REDACTED] who concurs with the diagnosis.

This report has been finalized at the [REDACTED]

<Sign Out Dr. Signature>

HPV/A Discrepancy		X
Prior Malignancy History	CEVIX	X
Reviewed: [Signature]	Date Reviewed: 11/14/12	

Source: NCI Genomic Data Commons file 9ab83db1-8e08-4fe9-a802-e360ce4b1fd6 (TCGA-56-A4ZJ.94A1F143-A043-4277-8DD7-E248DF53C1C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).